Somatic mutation profile of tumor specimen TARGET-20-PASFVP-09A (aliquot TARGET-20-PASFVP-09A-01D) from TARGET case TARGET-20-PASFVP, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.0 years (3,664 days).
Specimen TARGET-20-PASFVP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 254a44cd-99db-4fc0-b56a-b891eb7386fd.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASFVP-14A (Bone Marrow Normal), aliquot TARGET-20-PASFVP-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36b273bb-537e-4701-8627-7817c7b7b814

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Nonsense Mutation 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 90/220 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- RUNX1 | c.529C>T p.R177* (on ENST00000344691 / NM_001001890.3; = p.R204* on NM_001754.5) | Nonsense Mutation (SNP) | VAF 94/202 reads (47%) | catalogued as rs1569061768, CM992142, COSV55866185; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BCOR | c.2607T>A p.Y869* | Nonsense Mutation (SNP) | VAF 129/150 reads (86%) | catalogued as COSV60708517, COSV60712533; called by muse, mutect2, varscan2
